Gene-level copy-number profile of tumor specimen ALCH-B2PY-TTP1-A from ALCHEMIST case ALCH-B2PY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.6 years (22,118 days).
Specimen ALCH-B2PY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 139bee34-25d4-4f94-b6c8-9cc8f21e30c0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2PY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/5ed93dba-33f2-406d-86eb-f18cae5498fd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 90; copy number 1: 2,006; copy number 2: 51,121; copy number 3: 3,639; copy number 4: 1,523; copy number 5: 3; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 80 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:91,674,857–91,685,884, 2 genes: RNA5SP100, DRD5P1.
- chr3:50,558,025–50,672,048, 6 genes: C3orf18, HEMK1, AC096920.1, CISH, MAPKAPK3, LINC02019.
- chr6:39,353,747–39,354,172, 1 gene (within-gene range 0–2): AL136087.1.
- chr7:76,531,319–76,541,459, 1 gene (within-gene range 0–2): SPDYE16.
- chr7:99,416,739–99,466,197, 5 genes (within-gene range 0–2): PTCD1, ATP5MF-PTCD1, CPSF4, AC073063.1, ATP5MF.
- chr7:102,537,918–102,690,469, 13 genes (within-gene range 0–2): POLR2J3, UPK3BL2, AC093668.1, SPDYE2, POLR2J3, RASA4, AC105052.4, AC105052.1, UPK3BL1, AC105052.3, SPDYE2B, POLR2J2, RASA4DP.
- chr9:123,485,529–123,493,156, 2 genes (within-gene range 0–2): MIR7150, AL445489.1.
- chr9:124,853,417–124,877,733, 3 genes: WDR38, RPL35, ARPC5L.
- chr9:124,887,410–124,887,549, 1 gene (within-gene range 0–2): RNU4-82P.
- chr14:90,489,010–90,491,637, 1 gene: AL096869.3.
- chr14:90,567,495–90,569,976, 1 gene (within-gene range 0–2): AL096869.1.
- chr15:25,178,738–25,211,877, 19 genes (within-gene range 0–1): SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23.
- chr15:25,220,497–25,225,284, 4 genes (within-gene range 0–1): SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:25,230,838–25,257,027, 13 genes (within-gene range 0–1): SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr16:67,975,663–67,980,549, 1 gene: DPEP3.
- chr17:2,720,801–2,723,947, 1 gene: AC005696.4.
- chr18:37,243,040–37,762,131, 6 genes (within-gene range 0–2): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:91,617,160–91,659,972, 1 gene, copy number 5 (within-gene range 1–5): LSP1P4.
- chr9:136,754,386–136,758,543, 1 gene, copy number 9: LCN8.
- chr9:136,791,344–136,800,595, 2 genes, copy number 5 (within-gene range 2–5): TMEM141, AL355987.3.

Autosomal genes at a single copy (total copy number 1): 1,956. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
